HCMI case HCM-BROD-1127-C15 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Esophagus. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/856282a3-fcad-4002-9190-64825ae6d77f

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1975; Vital status: Alive.

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C15.9; Tissue or organ of origin: Esophagus, NOS; Classification of tumor: primary; Age at diagnosis: 45.4 years (16,577 days); AJCC staging edition: 8th; AJCC clinical stage: Stage IVB; AJCC pathologic T: TX; AJCC pathologic N: NX; AJCC pathologic M: M1; AJCC pathologic stage: Stage IVB; Tumor grade: G3; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Prior treatment: No; Gastric esophageal junction involvement: Yes; Sites of involvement: Liver.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 0 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Irinotecan + Leucovorin; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 287 days; Days to treatment end: 287 days; Treatment outcome: Treatment Ongoing.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Immunotherapy (Including Vaccines), for residual disease; adjuvant Radiation Therapy, NOS, for residual disease; adjuvant Targeted Molecular Therapy, for residual disease.
2. Adenocarcinoma, metastatic, NOS: ICD-O-3 morphology code: 8140/6; ICD-10 code: C78.6; Tissue or organ of origin: Esophagus, NOS; Site of resection or biopsy: Peritoneum, NOS; Classification of tumor: metastasis; Age at diagnosis: 45.4 years (16,580 days); Days to diagnosis: 3 days; Gastric esophageal junction involvement: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Fluorouracil + Oxaliplatin; Treatment intent type: Maintenance Therapy; Regimen or line of therapy: FOLFOX; Days to treatment start: 28 days; Days to treatment end: 266 days; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Paclitaxel + Ramucirumab + Trastuzumab; Treatment intent type: Maintenance Therapy; Days to treatment start: 28 days; Days to treatment end: 266 days; Treatment outcome: Progressive Disease.

Follow-up (4 entries)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Liver; Days to progression: 0 days.
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Lymph nodes of multiple regions; Days to progression: 0 days.
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Adrenal gland, NOS; Days to progression: 0 days.
- Days to follow up: 335 days; Disease response: Progressive Disease; Progression or recurrence: Yes.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 80 kg; Height: 179 cm; BMI: 22.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol intensity: Occasional Drinker.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Esophageal Cancer.

Biospecimens (2 samples)
- Sample HCM-BROD-1127-C15-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-BROD-1127-C15-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 5.
